Gene-level copy-number profile of tumor specimen TCGA-C4-A0EZ-01A from TCGA case TCGA-C4-A0EZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 69.0 years (25,202 days).
Specimen TCGA-C4-A0EZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.68cef882-5ac4-4c7b-9d99-3bc3bc15d0fe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C4-A0EZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/883bf006-cc65-42af-8ac2-cc90fbf5918d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 673; copy number 2: 5,670; copy number 3: 29,965; copy number 4: 16,837; copy number 5: 5,631; copy number 6: 894; copy number 7: 80; copy number 8: 1; copy number 15: 31; copy number 32: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C4-A0EZ-01A-21D-A10T-01): tumor purity 0.93, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 148 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,958,989–86,074,429, 1 gene, copy number 15 (within-gene range 3–15): CADM2.
- chr3:85,799,987–88,467,594, 30 genes, copy number 15 (within-gene range 3–15): CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA.
- chr6:19,837,370–22,654,455, 29 genes, copy number 32 (within-gene range 3–32): ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1.
- chr6:22,569,566–23,404,132, 7 genes, copy number 32: HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1.
- chr7:38,291,616–38,292,078, 1 gene, copy number 8: TRGV11.
- chr14:21,868,839–22,502,292, 80 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 673. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
